CCDI case PBBLSZ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Meningiomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/88f238a0-11a5-4cf4-ba7b-abb6e8de6634

Demographics
Sex at birth: male; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Meningioma, NOS: ICD-O-3 morphology code: 9530/0; Tissue or organ of origin: Frontal lobe; Age at diagnosis: 17.8 years (6,500 days).

Biospecimens (3 samples)
- Sample 0DCEQP: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DCEQV: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DCER2: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
